Somatic mutation profile of tumor specimen TCGA-AG-3883-01A (aliquot TCGA-AG-3883-01A-02W-0899-10) from TCGA case TCGA-AG-3883, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.6 years (25,415 days).
Specimen TCGA-AG-3883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f77219d-b14c-4fbb-a6a7-695edb440ce0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3883-10A (Blood Derived Normal), aliquot TCGA-AG-3883-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/047274d0-445a-473f-b1ba-82731ba6c9cb

The open-access MAF lists 134 somatic variants for this specimen: 97 protein-altering or splice-affecting, 32 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 32, Nonsense Mutation 6, Intron 4, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 116/318 reads (36%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, varscan2
- FBN1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs730880099, CD040176, CM970507, COSV57313786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 164/368 reads (45%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTL9 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs781910740, COSV61006476; called by muse, mutect2, varscan2
- ADAM12 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs763136025, COSV64103186; called by muse, mutect2, varscan2
- AGPAT4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs1158616160, COSV57245733; called by muse, mutect2, varscan2
- AHSG | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374704176; called by muse, mutect2
- ALLC | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs755429246, COSV52994164, COSV99378331; called by muse, mutect2, varscan2
- ANGEL2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 151/357 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV64736935; called by muse, mutect2, varscan2
- ARFGEF3 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as rs747544365, COSV52450223; called by muse, mutect2, varscan2
- ASTN2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs138260564; called by muse, mutect2, varscan2
- BCLAF1 | c.2506G>C p.D836H | Missense Mutation (SNP) | VAF 117/753 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50356976; called by muse, mutect2, varscan2
- C12orf42 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV100172068; called by muse, mutect2, varscan2
- C3orf20 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs370846039; called by muse, mutect2, varscan2
- COBLL1 | c.1741G>C p.D581H (on ENST00000392717; = p.D543H on NM_014900.5) | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1386416934, COSV99527731; called by muse, mutect2, varscan2
- COPB1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1324244888, COSV99999473; called by muse, mutect2, varscan2
- CWF19L2 | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 132/959 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1280738478, COSV56509524; called by muse, mutect2, varscan2
- CYGB | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373180768; called by muse, mutect2, varscan2
- DACH2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 197/301 reads (65%) | SIFT tolerated (0.87); PolyPhen benign (0.109); catalogued as rs754406197, COSV64162340; called by muse, mutect2, varscan2
- DAGLA | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs377269260; called by muse, mutect2, varscan2
- DCLK2 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV104402838, COSV56200263; called by muse, mutect2, varscan2
- DDX43 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943943; called by muse, mutect2, varscan2
- EDAR | c.966T>G p.I322M | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.372); catalogued as COSV51500278; called by muse, mutect2, varscan2
- ENPEP | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs763798263, COSV54456976; called by muse, mutect2, varscan2
- ERMP1 | c.2366A>C p.K789T | Missense Mutation (SNP) | VAF 179/902 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV53036363; called by muse, mutect2, varscan2
- EXOC7 | c.1186G>A p.D396N (on ENST00000335146 / NM_001145297.4; = p.D314N on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs372862629; called by muse, mutect2, varscan2
- FAT4 | c.12356C>A p.P4119Q | Missense Mutation (SNP) | VAF 116/301 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1403495139, COSV58701077, COSV58712338; called by muse, mutect2, varscan2
- FBXO47 | c.944T>A p.V315D | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100960670; called by muse, mutect2
- FHL5 | c.681A>T p.K227N | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV100459309; called by muse, mutect2, varscan2
- FLG | c.4408C>A p.H1470N | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs757429282, COSV100911450, COSV100912442; called by muse, mutect2, varscan2
- FOXK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61064938; called by muse, mutect2, varscan2
- GDF6 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316172715, COSV54623136; called by muse, mutect2, varscan2
- GIGYF2 | c.1670G>A p.W557* | Nonsense Mutation (SNP) | VAF 490/1132 reads (43%) | catalogued as COSV101004242; called by muse, mutect2, varscan2
- GJD2 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.195); catalogued as COSV51747284, COSV99290830; called by muse, mutect2, varscan2
- GPR37L1 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs374873137; called by muse, mutect2, varscan2
- GRIA4 | c.457T>A p.C153S | Missense Mutation (SNP) | VAF 64/533 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99230518; called by muse, mutect2, varscan2
- IFI44L | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1391612787, COSV60726873; called by muse, mutect2, varscan2
- IREB2 | c.1337G>C p.S446T | Missense Mutation (SNP) | VAF 50/962 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99359288; called by muse, mutect2
- JMJD1C | c.2374C>T p.H792Y | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101232329; called by muse, mutect2, varscan2
- KCNQ5 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 61/493 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs866590945, COSV100572979, COSV59667758; called by muse, mutect2, varscan2
- KRT82 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs149755657; called by muse, varscan2
- LARGE2 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99138352; called by muse, mutect2
- LRP1B | c.6872C>A p.S2291* | Nonsense Mutation (SNP) | VAF 57/451 reads (13%) | catalogued as COSV101255326; called by muse, mutect2, varscan2
- LRP2 | c.6331T>C p.W2111R | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99787739; called by muse, mutect2, varscan2
- LVRN | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV63496326; called by muse, mutect2
- MAP3K13 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1465764941, COSV53984195, COSV53984539; called by muse, mutect2, varscan2
- MIB1 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.969); catalogued as COSV55088241, COSV99838598; called by muse, mutect2, varscan2
- MSRB3 | c.211T>A p.F71I | Missense Mutation (SNP) | VAF 185/602 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57588199; called by muse, mutect2, varscan2
- MYO3A | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV99779264; called by muse, mutect2, varscan2
- NCAM2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV99522554; called by muse, mutect2, varscan2
- NFATC2 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs553983994, COSV65359200; called by muse, mutect2, varscan2
- NGB | c.125T>C p.F42S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV100030046; called by muse, mutect2, varscan2
- NSUN3 | c.145T>G p.C49G | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV58934163; called by muse, mutect2, varscan2
- NTN1 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs376278603; called by muse, mutect2, varscan2
- NUGGC | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778149850, COSV100429154; called by muse, mutect2, varscan2
- NYAP2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 168/395 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); catalogued as rs568027472, COSV99796316; called by muse, mutect2, varscan2
- ODF2 | c.2441C>A p.S814Y (on ENST00000434106 / NM_153433.2; = p.S790Y on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1481087609, COSV59406569; called by muse, mutect2, varscan2
- OR5A2 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100119718; called by muse, mutect2, varscan2
- OR9G1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 49/574 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.043); catalogued as COSV100380348, COSV56447504; called by muse, mutect2
- PCDHB7 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV99176797; called by muse, mutect2, varscan2
- PDYN | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373922212, CM150324, COSV54100679; called by muse, mutect2, varscan2
- PIK3C2G | c.4099C>A p.P1367T (on ENST00000676171; = p.P1326T on NM_004570.5) | Missense Mutation (SNP) | VAF 143/946 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV56842153; called by muse, mutect2, varscan2
- PTPRZ1 | c.6787C>T p.P2263S | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66431340, COSV66441867; called by muse, mutect2, varscan2
- PXDNL | c.3565G>A p.G1189S | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as rs371171299; called by muse, mutect2, varscan2
- RBM26 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 98/1027 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99936031; called by muse, mutect2, varscan2
- RERE | c.2131A>C p.T711P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV100555867, COSV61950634; called by muse, mutect2
- RGS22 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 506/1610 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs370599090; called by muse, varscan2
- RPL27 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99518473; called by muse, mutect2
- SCARA5 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 48/92 reads (52%) | catalogued as COSV100107796; called by muse, mutect2, varscan2
- SCN9A | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 177/592 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.439); catalogued as COSV100312312; called by muse, mutect2, varscan2
- SENP5 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV100051935; called by muse, mutect2
- SLC4A3 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV56091906; called by muse, varscan2
- SMARCAL1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 117/288 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as COSV100619856; called by muse, mutect2, varscan2
- SOGA3 | c.1407T>A p.N469K | Missense Mutation (SNP) | VAF 229/792 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100846873; called by muse, mutect2, varscan2
- SOX6 | c.2116C>T p.R706W (on ENST00000528429 / NM_001145819.2; = p.R679W on NM_017508.3) | Missense Mutation (SNP) | VAF 156/416 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57036613; called by muse, mutect2, varscan2
- SOX6 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100321854; called by muse, mutect2, varscan2
- SPTAN1 | c.5708C>A p.A1903D | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100823447, COSV63987995; called by muse, mutect2
- SSTR4 | c.710A>T p.K237M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99658375; called by muse, mutect2
- TAS2R9 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV53688024; called by muse, mutect2, varscan2
- TESPA1 | c.1262C>T p.T421M (on ENST00000316577 / NM_001098815.3; = p.T283M on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 178/637 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs148518799; called by muse, mutect2, varscan2
- TLX1 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64622326; called by muse, mutect2, varscan2
- TMEM132D | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1280927732, COSV67160048; called by muse, mutect2, varscan2
- TMEM25 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.102); catalogued as rs75184401, COSV100244755; called by muse, mutect2, varscan2
- TPP2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202026163, COSV101060235; called by muse, mutect2, varscan2
- TTK | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100036185, COSV57885694; called by muse, mutect2, varscan2
- VCAN | c.5353G>T p.E1785* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99424300, COSV99425333; called by muse, mutect2, varscan2
- VLDLR | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 88/234 reads (38%) | catalogued as COSV101173626, COSV66077148; called by muse, mutect2, varscan2
- XIRP1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs370513707; called by muse, mutect2, varscan2
- ZBED9 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs756634654, COSV71729506; called by muse, mutect2, varscan2
- ZEB2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs746958005, COSV57955437; called by muse, mutect2, varscan2
- ZHX2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1563602214, COSV100072874, COSV100073762, COSV100074060; called by muse, mutect2, varscan2
- ZNF277 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1378565434, COSV62463351; called by muse, mutect2, varscan2
- ZNF808 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 108/810 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63118831; called by muse, mutect2, varscan2
- ANK1 | c.5298dup p.E1767Rfs*3 | Frame Shift Ins (INS) | VAF 34/319 reads (11%) | called by mutect2, pindel
- COPS6 | c.209_211dup p.G70dup | In Frame Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- INTS4 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MMP19 | c.88-2_88-1del p.X30_splice | Splice Site (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel, varscan2
- AMN1 | c.687A>G p.G229= | Silent (SNP) | VAF 43/296 reads (15%) | catalogued as COSV55670460; called by muse, mutect2, varscan2
- C10orf90 | c.1980G>A p.P660= | Silent (SNP) | VAF 80/207 reads (39%) | catalogued as rs200783026, COSV52950179; called by muse, mutect2, varscan2
- CDH10 | c.384C>T p.R128= | Silent (SNP) | VAF 82/303 reads (27%) | catalogued as rs768905224, COSV52568657, COSV52580692; called by muse, mutect2, varscan2
- CEP70 | c.1677C>T p.H559= | Silent (SNP) | VAF 64/450 reads (14%) | catalogued as rs758222104, COSV53874497; called by muse, mutect2, varscan2
- COL12A1 | c.30C>T p.A10= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV59390540; called by muse, mutect2, varscan2
- DSCAML1 | c.3525G>A p.P1175= (on ENST00000321322; = p.P1115= on NM_020693.4) | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs572641245, COSV58382976; called by muse, mutect2, varscan2
- ELAVL4 | c.1140C>A p.S380= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV63914743; called by muse, mutect2, varscan2
- GALNT15 | c.306C>T p.P102= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV60215600; called by muse, mutect2, varscan2
- H2AC11 | c.100C>T p.L34= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs746426831, COSV100345991, COSV60361753; called by muse, mutect2
- HMGCLL1 | c.18C>T p.S6= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1273698182, COSV51441144; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1159A>C p.R387= | Silent (SNP) | VAF 98/235 reads (42%) | catalogued as rs372925400, COSV61144693; called by muse, mutect2, varscan2
- KCNB2 | c.228G>C p.V76= | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as COSV73049111; called by muse, mutect2, varscan2
- KIF6 | c.1968C>T p.R656= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as COSV54668538; called by muse, mutect2, varscan2
- LSS | c.2148C>T p.L716= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs372838581; called by muse, mutect2, varscan2
- MAGEC2 | c.300G>A p.L100= | Silent (SNP) | VAF 289/430 reads (67%) | catalogued as rs528011223, COSV55998085; called by muse, mutect2, varscan2
- MED15 | c.822G>A p.P274= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs201812389, COSV53027158; called by muse, mutect2, varscan2
- MOV10 | c.1134G>A p.T378= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs114735246, COSV62490828; called by muse, mutect2, varscan2
- NLGN4X | c.1041C>T p.D347= | Silent (SNP) | VAF 59/75 reads (79%) | catalogued as rs747986438, COSV52006388; called by muse, mutect2, varscan2
- NUP155 | c.2805G>A p.T935= (on ENST00000231498 / NM_153485.3; = p.T876= on NM_004298.4) | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as COSV51527452; called by muse, mutect2, varscan2
- OR8H1 | c.534C>T p.C178= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as rs374019056; called by muse, mutect2, varscan2
- PSIP1 | c.1062G>A p.R354= | Silent (SNP) | VAF 104/360 reads (29%) | catalogued as COSV66253776; called by muse, varscan2
- PTPN18 | c.945C>T p.D315= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs551564117, COSV51558227; called by muse, mutect2, varscan2
- RERE | c.2133G>T p.T711= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100555865; called by muse, mutect2
- SFRP2 | c.705G>A p.S235= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs143701440; called by muse, mutect2, varscan2
- SLC22A7 | c.1503C>T p.I501= (on ENST00000372585 / NM_153320.2; = p.I499= on NM_006672.3) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs773467630, COSV51482977, COSV99240213; called by muse, varscan2
- SLC24A3 | c.1098C>T p.N366= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs370751183; called by muse, mutect2, varscan2
- SLTM | c.1347G>A p.E449= | Silent (SNP) | VAF 45/194 reads (23%) | catalogued as COSV51053307; called by muse, mutect2, varscan2
- TACC2 | c.4494G>T p.L1498= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV57747898; called by muse, mutect2, varscan2
- TKFC | c.879G>A p.V293= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs372987609, COSV101204144; called by muse, mutect2
- TRPM3 | c.1656C>T p.F552= (on ENST00000357533 / NM_001366142.2; = p.F397= on NM_024971.6) | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as rs201162468; called by muse, mutect2, varscan2
- TUBA3C | c.330C>T p.I110= | Silent (SNP) | VAF 48/199 reads (24%) | catalogued as rs1486793465, COSV67138923; called by muse, mutect2, varscan2
- ZP1 | c.1206C>T p.P402= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs151198562, COSV53923109; called by muse, mutect2, varscan2
- AC024940.1 | n.4581C>T | RNA (SNP) | VAF 61/226 reads (27%) | called by muse, mutect2, varscan2
- DENND1A | c.1577+810G>C | Intron (SNP) | VAF 20/113 reads (18%) | catalogued as rs184395895, COSV101011032; called by muse, mutect2, varscan2
- NRG1 | c.502+31054_502+31055del | Intron (DEL) | VAF 37/121 reads (31%) | called by pindel, varscan2
- PCDH11X | c.3033+3672G>T | Intron (SNP) | VAF 427/604 reads (71%) | catalogued as COSV53446446; called by muse, mutect2, varscan2
- WNK1 | c.2140-2856dup | Intron (INS) | VAF 56/181 reads (31%) | called by mutect2, pindel, varscan2
